PECGS case C083-000036 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/a6685e66-30b8-4fa8-aaf3-cb3942e596b7

Demographics
Sex at birth: female; Age at index: 87 years; Year of birth: 1935; Education level: Vocational College or Some College.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Age at diagnosis: 86.9 years (31,740 days); AJCC pathologic stage: Stage IIA; Progression or recurrence: yes; Days to last follow up: 497 days (1.4 years).

Other clinical attributes
- BMI: 50.29; Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: No.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000036_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000036_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
